MMRF case MMRF_1947 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cfce9dc2-683b-46fc-bbf5-0e46bc20b2ae

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.3 years (23,109 days); ISS stage: II; Days to last known disease status: 1,043 days (2.9 years); Days to last follow up: 1,043 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 80 days; Days to treatment end: 80 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 105 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 287 days; Days to treatment end: 290 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 289 days; Days to treatment end: 289 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 291 days; Days to treatment end: 291 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -24 (ECOG 0): M Protein 3.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 90.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 36 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.54 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 34 g/L; Total Protein 9.7 g/dL; Glucose 4.4 mmol/L.
- Day 80 (ECOG 0): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.913 mg/dL; Immunoglobulin G 8.11 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.45 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.24 mmol/L.
- Day 119 (ECOG 1): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.998 mg/dL; Immunoglobulin G 9.2 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 8.55 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 70 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.
- Day 200 (ECOG 0): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 2.15 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 190 ×10⁹/L.
- Day 301 (ECOG 2): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.877 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 14.4 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 42 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 5.89 mmol/L.
- Day 407 (ECOG 0): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.68 g/L; Beta 2 Microglobulin 2.47 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 4.62 mmol/L.
- Day 499 (ECOG 0): M Protein 0.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 2.22 g/L; Lactate Dehydrogenase 9.25 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 7.5 g/dL; Glucose 5.28 mmol/L.
- Day 589 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.55 g/L; Immunoglobulin M 0.82 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 4.57 mmol/L.
- Day 694 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.84 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 4.79 mmol/L.
- Day 785 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.77 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 4.02 mmol/L.
- Day 875 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.92 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 4.68 mmol/L.
- Day 967 (ECOG 0): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.81 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.29 mmol/L.
- Day 1,043 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.88 g/L; Immunoglobulin M 0.79 g/L; Beta 2 Microglobulin 1.2 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.9 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -24: Weight: 63 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1947_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -24 days.
- Sample MMRF_1947_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -24 days.
